Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46E, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46E-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LEFT PELVIC LYMPH NODES, LYMPHADENECTOMY -

- A. SIX BENIGN LYMPH NODES (0/6).
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: RIGHT PELVIC LYMPH NODES, LYMPHADENECTOMY -

- A. THREE BENIGN LYMPH NODES (0/3).
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE WITH A FOCAL INTRADUCTAL COMPONENT, GLEASON SCORE 4+4 = 8, INVOLVING THE RIGHT MID THROUGH RIGHT BASE PROSTATE (SLIDES 30-3R, 3RR). MAXIMAL TUMOR DIAMETER OF THIS FOCUS IS 1 CM (SLIDE 3P).
- B. SEPARATE SMALL FOCUS OF PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+3 = 6, PRESENT IN THE RIGHT POSTERIOR MID-PROSTATE (SLIDE 3AA). MAXIMAL TUMOR DIAMETER OF THIS FOCUS IS 0.4 CM.
- C. SEPARATE FOCUS OF PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+4 = 7, INVOLVING THE LEFT LATERAL APEX (IDENTIFIED BY THE PRIOR PROSTATE NEEDLE BIOPSY).
- D. CARCINOMA COMPRISES LESS THAN 5% OF THE SAMPLED PROSTATE GLAND VOLUME.
- E. FOCAL AND ESTABLISHED EXTRACAPSULAR EXTENSION ARE PRESENT IN THE RIGHT ANTERIOR MID (SLIDE 3P) AND RIGHT ANTERIOR BASE (SLIDE 3R) PROSTATE, RESPECTIVELY.
- F. NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- G. CARCINOMATOUS PERINEURAL INVASION IS PRESENT (SLIDE 3P, 3Q, 3R).
- H. FOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (SLIDE 3S).
- I. ALL SURGICAL RESECTION MARGINS EXAMINED ARE FREE OF NEOPLASIA.
- J. BENIGN BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA.
- K. NON-NEOPLASTIC PROSTATIC TISSUE WITH FOCAL CHRONIC INFLAMMATION, WIDESPREAD GLANDULAR ATROPHY AND FOCAL PERICAPSULAR HEMOSIDERIN DEPOSITION (SUGGESTING A PRIOR BIOPSY SITE).
- L. ORGANIZED THROMBUS IS PRESENT IN A PERIPROSTATIC VEIN (SLIDES 30-3T, 3BB, 3CC).
- M. TNM PATHOLOGIC STAGE: T3a N0 MX.
- N. HISTOLOGIC GRADE: G3-4 (See synoptic).

ICD - 0 - 3

CLINICAL DATA: PSA value: 2.0
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 90%
WEIGHT OF PROSTATE: 39.13gm
TUMOR SIZE: Maximum dimension: 1 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: < 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 9
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated
Comment: Carcinoma is limited to the right lobe in the radical prostatectomy specimen sections; however, the prior prostate biopsy had carcinoma in a left lateral apex core.

adenocarcinoma, acinar 8550/3

Site: prostate, NOS 661.9

hw
9/27/12

[page 2 of 2]
FINAL DIAGNOSIS:**PART 1: LEFT PELVIC LYMPH NODES, LYMPHADENECTOMY -**

- A. SIX BENIGN LYMPH NODES (0/6).
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: RIGHT PELVIC LYMPH NODES, LYMPHADENECTOMY -

- A. THREE BENIGN LYMPH NODES (0/3).
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE WITH A FOCAL INTRADUCTAL COMPONENT, GLEASON SCORE 4+4 = 8, INVOLVING THE RIGHT MID THROUGH RIGHT BASE PROSTATE (SLIDES 3O-3R, 3RR). MAXIMAL TUMOR DIAMETER OF THIS FOCUS IS 1 CM (SLIDE 3P).
- B. SEPARATE SMALL FOCUS OF PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+3 = 6, PRESENT IN THE RIGHT POSTERIOR MID-PROSTATE (SLIDE 3AA). MAXIMAL TUMOR DIAMETER OF THIS FOCUS IS 0.4 CM.
- C. SEPARATE FOCUS OF PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+4 = 7, INVOLVING THE LEFT LATERAL APEX (IDENTIFIED BY THE PRIOR PROSTATE NEEDLE BIOPSY;
- D. CARCINOMA COMPRISES LESS THAN 5% OF THE SAMPLED PROSTATE GLAND VOLUME.
- E. FOCAL AND ESTABLISHED EXTRACAPSULAR EXTENSION ARE PRESENT IN THE RIGHT ANTERIOR MID (SLIDE 3P) AND RIGHT ANTERIOR BASE (SLIDE 3R) PROSTATE, RESPECTIVELY.
- F. NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- G. CARCINOMATOUS PERINEURAL INVASION IS PRESENT (SLIDE 3P, 3Q, 3R).
- H. FOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (SLIDE 3S).
- I. ALL SURGICAL RESECTION MARGINS EXAMINED ARE FREE OF NEOPLASIA.
- J. BENIGN BILATERAL SEMINAL VESICLES AND BILATERAL DISTAL VASA DEFERENTIA.
- K. NON-NEOPLASTIC PROSTATIC TISSUE WITH FOCAL CHRONIC INFLAMMATION, WIDESPREAD GLANDULAR ATROPHY AND FOCAL PERICAPSULAR HEMOSIDERIN DEPOSITION (SUGGESTING A PRIOR BIOPSY SITE).
- L. ORGANIZED THROMBUS IS PRESENT IN A PERIPROSTATIC VEIN (SLIDES 3O-3T, 3BB, 3CC).
- M. TNM PATHOLOGIC STAGE: T3a N0 MX.
- N. HISTOLOGIC GRADE: G3-4 (See synoptic).

CLINICAL DATA:	PSA value: 2.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	90%
WEIGHT OF PROSTATE:	39.13gm
TUMOR SIZE:	Maximum dimension: 1 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	9
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	Carcinoma is limited to the right lobe in the radical prostatectomy specimen sections; however, the prior prostate biopsy had carcinoma in a left lateral apex core.

Source: NCI Genomic Data Commons file 3730f1a5-c90c-42d2-a7fd-390b65c2c152 (TCGA-EJ-A46E.F2A59B31-7CFE-4DA8-A7B7-229021357746.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).